Somatic mutation profile of tumor specimen MMRF_1638_1_BM_CD138pos (aliquot MMRF_1638_1_BM_CD138pos_T1_KHS5U_L12926) from MMRF case MMRF_1638, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.9 years (24,082 days).
Specimen MMRF_1638_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac37aeb0-7e07-4cc1-9938-12bbe0a391b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1638_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1638_1_PB_WBC_C2_KHS5U_L12860; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2330be2-5bde-4c43-83aa-8e4c0fffcd41

The open-access MAF lists 164 somatic variants for this specimen: 68 protein-altering or splice-affecting, 17 silent, 79 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, 3'UTR 41, Intron 19, Silent 17, 5'UTR 9, 3'Flank 5, Nonsense Mutation 4, Splice Site 3, Frame Shift Ins 3, 5'Flank 3, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1516G>A p.G506R (on ENST00000288602 / NM_001374244.1; = p.G466R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs121913353, COSV56064038, COSV56099462; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 72/140 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC24A4 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 50/114 reads (44%) | catalogued as rs587777535, CM133029, COSV100106383; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 96/179 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99536759; called by muse, mutect2, varscan2
- ADRA1A | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 25/355 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs938487720, COSV52362588; called by muse, mutect2
- ANAPC2 | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 73/126 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs373874420; called by muse, mutect2, varscan2
- BMP1 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60479869; called by muse, mutect2, varscan2
- C3orf56 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as rs1361816612; called by muse, mutect2, varscan2
- CAPG | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs145160691; called by muse, mutect2, varscan2
- CCDC96 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765102556; called by muse, mutect2
- CD8A | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as rs750796440, COSV52157831; called by muse, mutect2, varscan2
- CREB3L1 | c.1240G>A p.V414I | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs559259997, COSV55830395; called by muse, mutect2, varscan2
- DTNA | c.1382A>G p.D461G | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as rs774001402; called by muse, mutect2, varscan2
- GRIN3B | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 107/225 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs1288243158; called by muse, mutect2, varscan2
- H2BC11 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.782); catalogued as rs761821895; called by muse, mutect2, varscan2
- HIPK2 | c.2321A>G p.H774R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.921); catalogued as rs755249664; called by muse, mutect2, varscan2
- IGHV2-70 | c.13T>C p.C5R | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.27); PolyPhen benign (0.166); catalogued as rs539617414; called by mutect2, varscan2
- IGLL5 | c.206G>C p.R69T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as rs745485743, COSV73251123; called by mutect2, varscan2
- IGLV3-1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 83/207 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs144850905; called by muse, varscan2
- IGLV3-1 | c.131A>G p.D44G | Missense Mutation (SNP) | VAF 90/167 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs774199094; called by muse, varscan2
- IGLV3-1 | c.266C>G p.A89G | Missense Mutation (SNP) | VAF 110/196 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as rs373811509; called by muse, varscan2
- IGLV3-1 | c.313T>A p.Y105N | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs574479963; called by muse, varscan2
- ISM2 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 156/401 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773760758; called by muse, mutect2, varscan2
- KLRF2 | c.397C>A p.H133N | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.188); catalogued as rs975994987, COSV73374435; called by muse, mutect2, varscan2
- MAML2 | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 37/91 reads (41%) | catalogued as COSV73263846; called by muse, mutect2, varscan2
- MROH7 | c.2579G>A p.R860H | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs374919113; called by muse, mutect2, varscan2
- MYO7A | c.5245C>T p.R1749W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs757984734; ClinVar: uncertain significance; called by muse, varscan2
- NLGN4X | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 52/57 reads (91%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV52037533, COSV52040298; called by muse, mutect2, varscan2
- PDLIM3 | c.176C>T p.S59L (on ENST00000284770 / NM_001257963.1; = p.S226L on NM_014476.6) | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs747243505, COSV99507586; called by muse, mutect2, varscan2
- PSMD6 | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 136/203 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs149590354; called by muse, mutect2, varscan2
- SLC45A4 | c.790C>T p.R264C (on ENST00000517878 / NM_001286646.2; = p.R213C on NM_001080431.2) | Missense Mutation (SNP) | VAF 13/262 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs568756982, COSV50151527; called by muse, mutect2
- TMSB4X | c.-17G>A | Splice Region (SNP) | VAF 57/64 reads (89%) | catalogued as COSV66081965; called by muse, mutect2, varscan2
- TMSB4X | c.-17+1G>C | Splice Site (SNP) | VAF 57/64 reads (89%) | catalogued as COSV66081196, COSV66081636; called by muse, mutect2, varscan2
- TYK2 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs367584686; called by muse, mutect2, varscan2
- UGT2B4 | c.1265G>A p.S422N | Missense Mutation (SNP) | VAF 91/207 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV59319920, COSV59320441; called by muse, mutect2, varscan2
- UNC13C | c.17dup p.K7Qfs*10 | Frame Shift Ins (INS) | VAF 25/78 reads (32%) | catalogued as rs1340319567; called by mutect2, pindel, varscan2
- ZNF704 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59920484; called by muse, mutect2, varscan2
- AC011462.1 | c.1248G>C p.W416C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ALKAL2 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD16 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2
- ARFGEF3 | c.2114C>T p.S705F | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ATN1 | c.1624T>A p.Y542N | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- BAZ1B | c.2530A>G p.S844G | Missense Mutation (SNP) | VAF 146/238 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- C3orf49 | c.848dup p.N283Kfs*13 | Frame Shift Ins (INS) | VAF 66/132 reads (50%) | called by mutect2, pindel, varscan2
- CAPN6 | c.50A>G p.K17R | Missense Mutation (SNP) | VAF 98/109 reads (90%) | SIFT tolerated (0.35); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CASKIN1 | c.896C>T p.T299I | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- EWSR1 | c.1045+1G>A p.X349_splice | Splice Site (SNP) | VAF 86/191 reads (45%) | called by muse, mutect2, varscan2
- FOXC1 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- HBE1 | c.229A>T p.K77* | Nonsense Mutation (SNP) | VAF 180/288 reads (63%) | called by muse, mutect2, varscan2
- HNRNPA1 | c.425G>T p.S142I | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- KCTD19 | c.370A>G p.R124G | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- KDM3A | c.342+2T>C p.X114_splice | Splice Site (SNP) | VAF 33/87 reads (38%) | called by muse, mutect2, varscan2
- KRBA2 | c.869A>G p.K290R | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- LRP1B | c.10003A>C p.K3335Q | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP3K10 | c.2476C>T p.R826W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- OLIG1 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OTULIN | c.139T>A p.C47S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAX3 | c.718A>G p.R240G | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PIK3AP1 | c.1181A>C p.Y394S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RAB8A | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3D19 | c.1165A>G p.S389G | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- SSRP1 | c.1424_1426del p.G475del | In Frame Del (DEL) | VAF 35/69 reads (51%) | called by mutect2, pindel, varscan2
- SUCLA2 | c.566G>C p.G189A | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UNC5C | c.2369C>G p.T790R | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- WNT10A | c.768_769insCCAACAGCCTA p.N257Pfs*4 | Frame Shift Ins (INS) | VAF 9/31 reads (29%) | called by mutect2, pindel
- ZNF638 | c.3854C>A p.P1285Q | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- ZNF641 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- ZNF8 | c.1651A>C p.N551H | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ACHE | c.513G>A p.Q171= | Silent (SNP) | VAF 47/132 reads (36%) | called by muse, mutect2, varscan2
- DLGAP5 | c.912G>A p.K304= | Silent (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- DPYSL4 | c.1083C>T p.R361= | Silent (SNP) | VAF 51/128 reads (40%) | called by muse, mutect2, varscan2
- H2AC15 | c.255G>A p.Q85= | Silent (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.132T>C p.D44= | Silent (SNP) | VAF 60/166 reads (36%) | catalogued as rs373697673; called by muse, varscan2
- MUC17 | c.8205T>C p.T2735= | Silent (SNP) | VAF 107/435 reads (25%) | called by muse, mutect2, varscan2
- MUC5AC | c.1443G>A p.T481= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs780546438; called by muse, mutect2, varscan2
- MUC5B | c.15381C>T p.A5127= | Silent (SNP) | VAF 73/219 reads (33%) | catalogued as rs569178429, COSV71594347; called by muse, mutect2, varscan2
- MYH2 | c.2538G>A p.L846= | Silent (SNP) | VAF 18/220 reads (8%) | catalogued as COSV55430756; called by muse, mutect2
- NAT8L | c.900C>T p.R300= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as rs749720109; called by muse, mutect2, varscan2
- PNLIP | c.1071T>C p.Y357= | Silent (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- PUM2 | c.120T>G p.L40= | Silent (SNP) | VAF 125/325 reads (38%) | called by muse, mutect2, varscan2
- RASAL2 | c.1506C>A p.R502= | Silent (SNP) | VAF 27/171 reads (16%) | called by muse, mutect2, varscan2
- RHBDL1 | c.1246C>T p.L416= (on ENST00000219551 / NM_001318733.2; = p.L351= on NM_001278720.2) | Silent (SNP) | VAF 53/101 reads (52%) | catalogued as rs1459208641; called by muse, mutect2, varscan2
- SECISBP2L | c.300G>A p.P100= | Silent (SNP) | VAF 85/347 reads (24%) | catalogued as rs375212699; called by muse, mutect2, varscan2
- SLIT1 | c.4440G>A p.T1480= | Silent (SNP) | VAF 48/94 reads (51%) | catalogued as rs143588507; called by muse, mutect2, varscan2
- UROC1 | c.1806C>T p.N602= | Silent (SNP) | VAF 50/217 reads (23%) | catalogued as rs138856930, COSV52034016; called by muse, mutect2
- ADAMTS19 | c.*492G>A | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- AGAP1 | c.*333G>T | 3'UTR (SNP) | VAF 68/140 reads (49%) | called by muse, mutect2
- ANKRD44 | c.-164T>C | 5'UTR (SNP) | VAF 26/70 reads (37%) | called by muse, varscan2
- AOX1 | c.*26C>G | 3'UTR (SNP) | VAF 120/297 reads (40%) | called by muse, mutect2, varscan2
- ARID1B | c.3511+458T>C | Intron (SNP) | VAF 48/114 reads (42%) | called by muse, mutect2, varscan2
- ATP2A1 | c.219+70C>A | Intron (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- BBS7 | c.*846dup | 3'UTR (INS) | VAF 30/75 reads (40%) | called by mutect2, pindel, varscan2
- BCL7A | chr12:122021510 C>T | 5'Flank (SNP) | VAF 33/127 reads (26%) | catalogued as COSV55849809; called by muse, mutect2, varscan2
- CCDC159 | c.22-96G>C | Intron (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- CCDC88C | c.4442-1910G>A | Intron (SNP) | VAF 19/137 reads (14%) | catalogued as rs1175900222; called by muse, mutect2, varscan2
- CD83 | c.*883T>A | 3'UTR (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- CDH26 | c.1889-198A>T | Intron (SNP) | VAF 29/60 reads (48%) | catalogued as COSV99722010; called by muse, mutect2, varscan2
- CDK9 | c.*544A>T | 3'UTR (SNP) | VAF 8/50 reads (16%) | catalogued as rs866486004, COSV64724024; called by muse, varscan2
- CHRM2 | chr7:137018203 A>G | 3'Flank (SNP) | VAF 34/73 reads (47%) | catalogued as rs1247132907; called by muse, mutect2, varscan2
- CLINT1 | c.*1253C>A | 3'UTR (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- COQ7 | c.*1395T>A | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- CSTF3 | c.225+414A>G | Intron (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- DCAF12 | c.862-33G>A | Intron (SNP) | VAF 37/103 reads (36%) | catalogued as rs374048315; called by muse, mutect2, varscan2
- EFR3A | c.*806dup | 3'UTR (INS) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- EGLN3 | c.-303T>A | 5'UTR (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- ENPEP | c.*988C>T | 3'UTR (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- EPHB1 | c.*363_*364del | 3'UTR (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- FAM155B | c.-17C>T | 5'UTR (SNP) | VAF 22/22 reads (100%) | called by muse, varscan2
- FBXO21 | chr12:117144423 G>C | 3'Flank (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- FCSK | c.*458G>T | 3'UTR (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- GNAL | c.-184T>C | 5'UTR (SNP) | VAF 38/126 reads (30%) | called by muse, mutect2, varscan2
- HEPH | c.*163G>A | 3'UTR (SNP) | VAF 33/34 reads (97%) | called by muse, mutect2, varscan2
- HHAT | c.*1782G>A | 3'UTR (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- HMGN3 | c.-66C>T | 5'UTR (SNP) | VAF 111/240 reads (46%) | called by muse, mutect2, varscan2
- HNF4G | chr8:75564734 G>T | 3'Flank (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- IGF1R | c.*6856del | 3'UTR (DEL) | VAF 22/62 reads (35%) | catalogued as rs373035124; called by mutect2, pindel, varscan2
- KALRN | c.4929+22508del | Intron (DEL) | VAF 91/167 reads (54%) | called by mutect2, pindel, varscan2
- KCNJ3 | c.*1964del | 3'UTR (DEL) | VAF 46/117 reads (39%) | called by mutect2, pindel, varscan2
- KIF17 | c.*507C>A | 3'UTR (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- KPNA1 | c.*3436T>A | 3'UTR (SNP) | VAF 77/111 reads (69%) | called by muse, mutect2, varscan2
- LHFPL2 | c.*2535A>T | 3'UTR (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- LMX1A | c.*1907G>T | 3'UTR (SNP) | VAF 68/95 reads (72%) | called by muse, mutect2, varscan2
- LRPAP1 | c.*2638G>A | 3'UTR (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- LZTFL1 | c.*517G>A | 3'UTR (SNP) | VAF 31/40 reads (78%) | catalogued as rs937600380; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851281 C>T | 5'Flank (SNP) | VAF 104/133 reads (78%) | catalogued as rs867169972; called by muse, mutect2, varscan2
- MMP16 | c.*6093G>T | 3'UTR (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- MTMR9 | c.1114-452A>G | Intron (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- MYO1E | c.-127C>G | 5'UTR (SNP) | VAF 58/131 reads (44%) | called by muse, mutect2, varscan2
- NDST2 | c.*301T>C | 3'UTR (SNP) | VAF 62/131 reads (47%) | called by muse, mutect2, varscan2
- NLGN1 | c.*871T>C | 3'UTR (SNP) | VAF 29/48 reads (60%) | catalogued as COSV64332293; called by muse, mutect2, varscan2
- NOVA1 | c.519+38C>T | Intron (SNP) | VAF 22/55 reads (40%) | catalogued as rs369041166; called by muse, mutect2, varscan2
- NRXN1 | c.*733G>A | 3'UTR (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.1846-13999G>T | Intron (SNP) | VAF 45/138 reads (33%) | called by muse, mutect2, varscan2
- PPP1R3D | c.*1573A>C | 3'UTR (SNP) | VAF 63/107 reads (59%) | called by muse, mutect2, varscan2
- PPP1R3D | c.*1353_*1354insG | 3'UTR (INS) | VAF 22/100 reads (22%) | called by pindel, varscan2
- PRND | c.*191T>G | 3'UTR (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- PTER | c.*1445A>T | 3'UTR (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- RAPGEF1 | c.*234G>A | 3'UTR (SNP) | VAF 98/166 reads (59%) | catalogued as rs1259626367; called by muse, mutect2, varscan2
- REM2 | c.*551G>A | 3'UTR (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- RFLNB | c.*173C>T | 3'UTR (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- RGL4 | c.-932A>G | 5'UTR (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- RGMA | c.*1038C>G | 3'UTR (SNP) | VAF 46/171 reads (27%) | catalogued as rs999078269; called by muse, mutect2, varscan2
- RGS18 | c.*940G>A | 3'UTR (SNP) | VAF 48/54 reads (89%) | called by muse, mutect2, varscan2
- RGS5 | c.*3687G>T | 3'UTR (SNP) | VAF 60/80 reads (75%) | called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.507+1821dup | Intron (INS) | VAF 30/119 reads (25%) | called by mutect2, pindel, varscan2
- S1PR3 | c.-148+873A>G | Intron (SNP) | VAF 46/140 reads (33%) | called by muse, mutect2, varscan2
- SCAPER | c.-60+29G>A | Intron (SNP) | VAF 92/184 reads (50%) | called by muse, mutect2, varscan2
- SHQ1 | chr3:72848450 A>T | 5'Flank (SNP) | VAF 38/177 reads (21%) | called by muse, mutect2, varscan2
- SLC2A1 | c.867+17A>G | Intron (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- SLC6A3 | c.*1469G>T | 3'UTR (SNP) | VAF 26/243 reads (11%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143627920 G>T | 3'Flank (SNP) | VAF 27/29 reads (93%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143627921 T>A | 3'Flank (SNP) | VAF 26/28 reads (93%) | called by muse, mutect2, varscan2
- SNX9 | c.*1011A>G | 3'UTR (SNP) | VAF 67/143 reads (47%) | called by muse, mutect2, varscan2
- SPATA8 | n.618G>T | RNA (SNP) | VAF 74/169 reads (44%) | called by muse, mutect2, varscan2
- SPIC | c.-18T>C | 5'UTR (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- TBC1D22A | c.*756C>T | 3'UTR (SNP) | VAF 31/213 reads (15%) | catalogued as rs374581574; called by muse, mutect2, varscan2
- TCF7L1 | c.-22G>A | 5'UTR (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- TMCC1 | c.*1320T>A | 3'UTR (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- UBE2I | c.*1978G>A | 3'UTR (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- ULK2 | c.*40+1958T>C | Intron (SNP) | VAF 42/108 reads (39%) | called by muse, mutect2, varscan2
- USP25 | c.45+13694T>G | Intron (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2
- USP38 | c.2967+46T>C | Intron (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- VN1R6P | n.240G>T | RNA (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- VPS37B | c.111+7590A>G | Intron (SNP) | VAF 4/8 reads (50%) | catalogued as rs941926056; called by muse, varscan2
